Somatic mutation profile of cancer-model specimen HCM-BROD-0923-C64-85B (3D Organoid, passage 6; aliquot HCM-BROD-0923-C64-85B-01D-A88G-36), derived from the primary tumor of HCMI case HCM-BROD-0923-C64, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 9.9 years (3,604 days).
Specimen HCM-BROD-0923-C64-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a549729a-79cf-46ea-ae0a-5085c50664d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0923-C64-10A (Blood Derived Normal), aliquot HCM-BROD-0923-C64-10A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47919a2e-e152-4437-8223-94836d2a04cb

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 4, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 217/432 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs121913407, COSV62687880, COSV62689248, COSV62696859; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MPP7 | c.1051G>A p.V351I | Missense Mutation (SNP) | VAF 205/674 reads (30%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs768470715; called by muse, mutect2, varscan2
- MSL2 | c.1169A>G p.N390S | Missense Mutation (SNP) | VAF 36/451 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs372296069; called by muse, mutect2
- NOTCH4 | c.3505C>T p.R1169W | Missense Mutation (SNP) | VAF 30/882 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.892); catalogued as rs764352594; called by muse, mutect2
- FOXD4L4 | c.33C>T p.S11= | Silent (SNP) | VAF 122/871 reads (14%) | called by muse, mutect2, varscan2
- GABRR2 | c.1260C>T p.A420= | Silent (SNP) | VAF 32/612 reads (5%) | called by muse, mutect2
- SEC16A | c.2562G>A p.E854= | Silent (SNP) | VAF 31/408 reads (8%) | called by muse, mutect2
